Somatic mutation profile of tumor specimen 0DWKGZ from CCDI case PBCNSI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.6 years (6,419 days).
Specimen 0DWKGZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 488b8ca3-9e8a-4659-8256-b5a8c87cab0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWKFY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87d7857b-e69d-4e01-9e34-ceba32f8305d

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITIH1 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 135/701 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs373768121; called by muse, mutect2, varscan2
- TMIGD1 | c.279T>A p.S93R | Missense Mutation (SNP) | VAF 141/597 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs764484067; called by muse, mutect2, varscan2
- TRIM26 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 115/506 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.621); catalogued as rs373978229; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 24/650 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, varscan2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- TAT | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 175/786 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 16/178 reads (9%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 5/38 reads (13%) | called by mutect2, varscan2
- NAPA | c.296-72G>A | Intron (SNP) | VAF 14/68 reads (21%) | catalogued as rs891416436; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 23/93 reads (25%) | called by muse, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 25/238 reads (11%) | called by muse, varscan2
- SLC44A1 | c.*75_*76insT | 3'UTR (INS) | VAF 6/93 reads (6%) | catalogued as COSV100570156; called by muse*, mutect2, varscan2*
